Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5701, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5701-01A (Primary Tumor).

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Left renal mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Left nephrectomy.

FINAL DIAGNOSIS:**PART 1: KIDNEY, LEFT, NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CONVENTIONAL CLEAR CELL TYPE, WITH FOCAL SARCOMATOID FEATURES.
- B. FUHRMAN'S NUCLEAR GRADE IS IV OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 9.5 CM.
- D. THE NEOPLASM EXTENDS THROUGH THE RENAL CAPSULE, BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- E. THE NEOPLASM EXTENDS INTO RENAL PELVIS ADIPOSE TISSUE.
- F. INVASION OF THE RENAL VEIN IS PRESENT.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY REVEALS ARTERIOLOSCLEROSIS, FOCAL GLOBAL AND SEGMENTAL GLOMERULOSCLEROSIS, AND FOCAL CYSTIC CHANGE.
- I. THE ADRENAL GLAND IS FREE OF TUMOR, WITH MILD CORTICAL HYPERPLASIA.
- J. TNM STAGE: pT3b N0 MX.

PART 2: LYMPH NODES, HILAR, EXCISION -

NO TUMOR SEEN IN FOUR LYMPH NODES (0/4).

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY KIDNEY TUMORS**

SPECIMEN TYPE: Radical nephrectomy

LATERALITY: Left

TUMOR SITE: Middle

FOCALITY: Lower pole

TUMOR SIZE: Unifocal

Greatest dimension: 9.5 cm

Additional dimensions: 6 x 6 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor extension into perinephric tissues

Tumor extension into major veins

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

Sarcomatoid carcinoma arising in renal cell carcinoma

Subtype and % of sarcomatoid element: 5%

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G4

PATHOLOGIC STAGING (pTNM): pT3b

pN0

Number of regional lymph nodes examined: 4

Number of regional lymph nodes involved: 0

pMX

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Uninvolved by tumor

VENOUS (LARGE VESSEL) INVASION (V): Present

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

ADDITIONAL PATHOLOGIC FINDINGS: Glomerular disease (type): FOCAL GLOBAL AND SEGMENTAL

GLOMERULOSCLEROSIS

Other: ARTERIOLOSCLEROSIS

Source: NCI Genomic Data Commons file a583b1a0-ae13-40e0-a2ab-78a37995ef04 (TCGA-B0-5701.61DEF406-8BC0-4955-B59A-D1D43267C888.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).